Somatic mutation profile of tumor specimen MP2PRT-PAPZKR-TMP1-A (aliquot MP2PRT-PAPZKR-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZKR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,614 days).
Specimen MP2PRT-PAPZKR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dccb0791-1044-4427-9769-053964ab3c9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZKR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZKR-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bd8c8ea-9918-4824-be68-d73f3aa146cb

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C11 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 156/459 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1057519904; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BMP3 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 124/329 reads (38%) | catalogued as rs759472288; called by muse, mutect2, varscan2
- BSPRY | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs754582771; called by muse, mutect2, varscan2
- SLITRK5 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61527041; called by muse, mutect2, varscan2
- SORCS1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as rs767760730; called by muse, mutect2
- AL021546.1 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYOCD | c.243_244del p.I82Tfs*25 | Frame Shift Del (DEL) | VAF 62/230 reads (27%) | called by pindel, varscan2
- ABCA12 | c.6639G>A p.K2213= (on ENST00000272895 / NM_173076.3; = p.K1895= on NM_015657.3) | Silent (SNP) | VAF 12/279 reads (4%) | catalogued as rs1338369030, COSV55950751, COSV55951788; called by muse, mutect2
- GPR32 | c.1056C>T p.N352= | Silent (SNP) | VAF 86/486 reads (18%) | catalogued as rs752484782; called by muse, mutect2, varscan2
